Surgical pathology report (de-identified scan), TCGA case TCGA-18-3410, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Princess Margaret Hospital (Canada), specimen TCGA-18-3410-01A (Primary Tumor).

[page 1 of 3]
Surgical Pathology Consultation Report

* Addended *

SPECIMEN(S) RECEIVED

1. Bone: portion seventh rt rib
2. Lymph node: INF pulm ligament ST9
3. Lymph node: Interlobar ST11
4. LUNGS: Right lower lobe with 8th and 9th rib- bronchial resection margin/QS

DIAGNOSIS

1. Portion of seventh rib:
- Consistent with normal rib bone. (GROSS DIAGNOSIS ONLY)
2. Inferior pulmonary ligament ST9 lymph node:
- Negative for malignancy, lymph node.
3. Interlobar ST11 lymph node:
- Negative for malignancy, lymph node.
4. Right lower lobe of lung with 8th and 9th ribs, resection:
- Poorly differentiated squamous cell carcinoma, peripheral with invasion into the chest wall.
- Tumor greatest diameter 4 cm.
- Bronchial resection margin negative for tumor but show focal squamous metaplasia without atypia.
- Peribronchial lymph node negative for malignancy.
- Chest wall surgical resection margins negative for tumor.

COMMENT

After decalcification, the rib case will be examined again for bone invasion. Nevertheless, this appears to be an apparent complete resection of a pT3N0 carcinoma.

[page 2 of 3]
GROSS DESCRIPTION

1. The specimen container labeled with the patient' s name and as "Bone: portion seventh rt rib". Grossly the bone is unremarkable. No sections submitted for processing.
2. The specimen container labeled with the patient' s name and as "Lymph node: inferior pulmonary ligament ST9", contains 1 node measuring 1.2 x 0.7 x 0.5 cm in thickness received in 10% buffered formalin.
2A bisected node submitted in toto.
3. The specimen container labeled with the patient' s name and as "Lymph node: Interlobar ST11", contains a grey to black tissue measuring 0.6 x 0.5 x 0.4 cm. received in 10% buffered formalin.
3A submitted in toto.
4. The specimen container labeled with the patient' s name and as "Lungs: right lower lobe with 8th and 9th rib- bronchial resection margin", contains a right lower lobe of lung with attached chest wall which includes the 9th and 8th rib with layer of muscle tissue attached on the outer surface. The specimen overall measures 16.0 x 10.0 x 5.5 cm. The two ribs together measure 9.0 x 5.5 x about 2.0 cm in thickness. A line of staples SI are identified. A large nodule peripherally, white, solid and lobular measuring approximately 4.0 cm in maximum dimension. Between the rib and the tumor of the lung parenchyma is a portion of thickened fibrous tissue. This rubbery fibrous white-tan tissue measures 8.2 x 4.5 x 2.9 cm in maximum thickness. The lesion appears to extend into this fibrous region crossing the pleural surface. The lesion is 3.6 cm away from the bronchial resection margin. There is a small area of emphysematous change approximately 3.5 cm from the bronchial resection margin. Four pieces of tumor and 1 piece of lung taken for tissue frozen. Intraoperative consultation performed on the bronchial resection margin. Representative sections are submitted as follows:
4A-B bronchial resection, frozen section
4C segmental node
4D emphysematous area
E segmental node
F-G anterior resection margin of fibrous tissue
4H-I posterior resection margin of fibrous tissue

[page 3 of 3]
[REDACTED]

[REDACTED]

[REDACTED]

4J	superior resection margin of fibrous tissue
4K	inferior resection margin of fibrous tissue
4L-M	tumor in the lung parenchyma with respect to the fibrous
tissue	
4N-P	tumor with respect to the lung parenchyma
4Q-R	sections of consolidation and emphysematous change
Section of tumor fibrous tissue with respect to rib to be sent after decal	

[REDACTED]

Addendum Comment

Additional sections that include the decalcified rib bone and adjacent tumor shows peri-osteal invasion, but there does not appear to be invasion through the bony cortex into the rib bone. There is no change in the original diagnosis of the case.

Source: NCI Genomic Data Commons file f64ec22c-7200-4ef4-8226-74d8ad8626e2 (TCGA-18-3410.956030D1-C74C-4BB6-93D9-04EB5C786905.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).